Somatic mutation profile of tumor specimen 0DWD2C from CCDI case PBCNZE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,572 days).
Specimen 0DWD2C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7acc6a3-5b94-4b7c-b269-c186286bbe34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWD1P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02d306c4-8648-427d-81c5-606f5ca7bc99

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC26A6 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 134/560 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs748302737; called by muse, varscan2
- POT1 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 210/1663 reads (13%) | called by muse, mutect2, varscan2
- GDF10 | c.456G>A p.P152= | Silent (SNP) | VAF 104/340 reads (31%) | catalogued as rs782091841; called by muse, mutect2, varscan2
